Gene-level copy-number profile of tumor specimen TCGA-ZG-A9L0-01A from TCGA case TCGA-ZG-A9L0, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.3 years (26,055 days).
Specimen TCGA-ZG-A9L0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.7ab9c42f-4b36-4064-9d56-384194c3f934.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZG-A9L0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/015c3f41-9e31-41ea-a3ff-a003f4dd8d97

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 570; copy number 2: 940; copy number 3: 8,752; copy number 4: 13,369; copy number 5: 18,044; copy number 6: 18,019; copy number 7: 38; copy number 8: 17; copy number 9: 2; copy number 10: 1; copy number 12: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZG-A9L0-01A-11D-A41J-01): tumor purity 0.79, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:65,319,563–66,431,521, 12 genes (within-gene range 0–2): EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3.
- chr6:93,070,387–93,677,954, 4 genes: AL138731.1, COPS5P1, EPHA7, AL591519.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:99,985,045–100,341,715, 14 genes, copy number 12: AC078916.1, RPS4XP1, AC126474.1, UHRF1BP1L, AC126474.2, AC010203.2, GOLGA2P5, RN7SL176P, AC010203.1, MIR1827, ACTR6, DEPDC4, Y_RNA, SCYL2.

Autosomal genes at a single copy (total copy number 1): 570. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
